Somatic mutation profile of tumor specimen TCGA-BR-A4CR-01A (aliquot TCGA-BR-A4CR-01A-11D-A24D-08) from TCGA case TCGA-BR-A4CR, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Fundus of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.3 years (25,669 days).
Specimen TCGA-BR-A4CR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ec3b793-a0f4-4953-a570-65ed578fe7e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4CR-10A (Blood Derived Normal), aliquot TCGA-BR-A4CR-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bba276a5-52db-4395-b280-c83a1bb2b805

The open-access MAF lists 72 somatic variants for this specimen: 50 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 37, Silent 22, Frame Shift Del 5, Nonsense Mutation 3, Splice Region 3, Nonstop Mutation 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 83/89 reads (93%) | hotspot (GDC flag); catalogued as rs121913300, CM941205, COSV57297576, COSV57321266; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 49/56 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFF3 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.481); catalogued as COSV57843180; called by muse, mutect2, varscan2
- ANKRD50 | c.850C>A p.L284I | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.19); PolyPhen benign (0.056); catalogued as COSV72385196; called by muse, mutect2, varscan2
- CDC25B | c.145T>G p.S49A | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV99847524; called by muse, mutect2
- CDH12 | c.1757C>T p.T586I | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV66391444; called by muse, mutect2, varscan2
- CLUH | c.3054G>T p.E1018D (on ENST00000435359; = p.E1057D on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.042); catalogued as rs1362018621, COSV70928005; called by muse, mutect2, varscan2
- CNTNAP5 | c.3895G>A p.E1299K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs749409177, COSV70475881; called by muse, mutect2, varscan2
- CXCR5 | c.1108A>T p.T370S | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.007); catalogued as COSV52682525, COSV52689680; called by muse, mutect2, varscan2
- DAB2 | c.1748C>T p.A583V | Missense Mutation (SNP) | VAF 96/481 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs761659376, COSV57912775; called by muse, mutect2, varscan2
- DAGLA | c.1457G>A p.R486H | Missense Mutation (SNP) | VAF 123/391 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs755291866, COSV57193971; called by muse, mutect2, varscan2
- DNAH9 | c.6299C>T p.A2100V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as rs1330921449, COSV52337943; called by muse, mutect2, varscan2
- FAM183A | c.405G>T p.*135Yext*5 | Nonstop Mutation (SNP) | VAF 83/188 reads (44%) | catalogued as COSV58921591; called by muse, mutect2, varscan2
- FAM50B | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs763048166, COSV66654582; called by muse, mutect2, varscan2
- GJA10 | c.270G>T p.L90F | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65354858; called by muse, mutect2, varscan2
- GRM8 | c.1583C>T p.T528M | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs537365104, COSV58807793; called by muse, mutect2, varscan2
- HCN1 | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 85/103 reads (83%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as rs376072704; called by muse, mutect2, varscan2
- HELB | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as COSV56072472; called by muse, mutect2, varscan2
- IL17RB | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 10/27 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as COSV55472153; called by muse, mutect2, varscan2
- IRS4 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.265); catalogued as COSV64532862; called by muse, mutect2, varscan2
- KANSL1L | c.937T>A p.F313I | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); catalogued as COSV55990059; called by muse, mutect2, varscan2
- KLK1 | c.698T>A p.V233D | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV56826125; called by muse, mutect2, varscan2
- KLRG1 | c.461T>A p.I154N | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56942365; called by muse, mutect2, varscan2
- LAMA1 | c.2277G>A p.A759= | Splice Region (SNP) | VAF 27/30 reads (90%) | catalogued as rs377514465; called by muse, mutect2, varscan2
- MICAL3 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 92/179 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV52893138; called by muse, mutect2, varscan2
- MIGA2 | c.1390A>T p.S464C | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1477487816, COSV52976046; called by muse, mutect2
- MRGPRX2 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV61673854; called by muse, mutect2, varscan2
- NPR3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 78/465 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561075244, COSV54085059; called by muse, mutect2, varscan2
- OR4K2 | c.228C>A p.F76L | Missense Mutation (SNP) | VAF 42/223 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); catalogued as COSV53848469; called by muse, mutect2, varscan2
- PEF1 | c.483C>T p.N161= | Splice Region (SNP) | VAF 6/48 reads (13%) | catalogued as COSV65483416; called by muse, mutect2, varscan2
- PIK3CD | c.2704C>T p.R902* | Nonsense Mutation (SNP) | VAF 114/264 reads (43%) | catalogued as COSV63126755; called by muse, mutect2, varscan2
- PRRC2B | c.885G>C p.Q295H | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.556); catalogued as COSV61934429; called by muse, mutect2, varscan2
- PSMA3 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV53616490; called by muse, mutect2, varscan2
- RAB27B | c.361G>T p.A121S | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.808); catalogued as COSV50494384; called by muse, mutect2, varscan2
- SCN10A | c.2651T>G p.L884R | Missense Mutation (SNP) | VAF 41/141 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71860502; called by muse, mutect2, varscan2
- SLC7A10 | c.251del p.G84Afs*2 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as COSV99471977; called by pindel, varscan2*
- SPSB4 | c.694C>A p.P232T | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.487); catalogued as COSV60144515, COSV60145595; called by muse, mutect2, varscan2
- ST7L | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 60/155 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV58307558; called by muse, mutect2, varscan2
- TNC | c.2134T>C p.L712= | Splice Region (SNP) | VAF 9/51 reads (18%) | catalogued as rs781375912, COSV60781414; called by muse, mutect2, varscan2
- ULK1 | c.2517G>C p.E839D | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV100416478, COSV58855057; called by muse, mutect2, varscan2
- VAV1 | c.1016T>A p.L339H | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58379770; called by muse, mutect2, varscan2
- ZBED9 | c.3767A>G p.D1256G | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV71729218; called by muse, mutect2, varscan2
- ZNF253 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as COSV63036534; called by muse, mutect2, varscan2
- ZNF705A | c.679C>G p.P227A | Missense Mutation (SNP) | VAF 36/230 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as COSV100828266; called by muse, mutect2, varscan2
- ZNF98 | c.1052A>T p.K351I | Missense Mutation (SNP) | VAF 31/42 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV63335018; called by muse, mutect2, varscan2
- CCDC170 | c.1718del p.T573Ifs*11 | Frame Shift Del (DEL) | VAF 81/235 reads (34%) | called by mutect2, pindel, varscan2
- DNAH2 | c.729A>T p.Q243H | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2
- KCNQ2 | c.1340_1356del p.P447Qfs*68 (on ENST00000359125 / NM_172107.4; = p.P419Qfs*68 on NM_004518.6) | Frame Shift Del (DEL) | VAF 19/71 reads (27%) | called by mutect2, pindel, varscan2
- MYO16 | c.1316del p.L439Cfs*73 | Frame Shift Del (DEL) | VAF 36/177 reads (20%) | called by mutect2, pindel, varscan2
- PRKD1 | c.1198del p.T400Qfs*8 | Frame Shift Del (DEL) | VAF 72/203 reads (35%) | called by mutect2, pindel, varscan2
- ATG9B | c.2073T>C p.T691= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV52486945; called by muse, mutect2, varscan2
- CACNB4 | c.357C>T p.S119= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs1358235093, COSV52390067; called by muse, mutect2, varscan2
- CCER1 | c.699C>T p.N233= | Silent (SNP) | VAF 231/422 reads (55%) | catalogued as COSV62646126, COSV62648331; called by muse, mutect2, varscan2
- CYP11A1 | c.489C>A p.A163= | Silent (SNP) | VAF 88/107 reads (82%) | catalogued as COSV51430860; called by muse, mutect2, varscan2
- DPP6 | c.522T>A p.T174= (on ENST00000377770 / NM_001364500.2; = p.T112= on NM_001936.5) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs531709235, COSV100127536, COSV59601120; called by muse, mutect2, varscan2
- H4C6 | c.144G>T p.S48= | Silent (SNP) | VAF 25/99 reads (25%) | catalogued as COSV66685439; called by muse, mutect2, varscan2
- HMGCLL1 | c.432A>G p.P144= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV51441466; called by muse, mutect2, varscan2
- IKZF1 | c.540C>T p.Y180= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as rs1470297332, COSV58781281; called by muse, mutect2, varscan2
- LAMC3 | c.1089C>T p.H363= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV63088986; called by muse, mutect2, varscan2
- MAP1B | c.771C>T p.L257= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV57094905; called by muse, mutect2, varscan2
- OR4K1 | c.519G>A p.E173= | Silent (SNP) | VAF 18/131 reads (14%) | catalogued as rs150151690; called by muse, mutect2, varscan2
- OR4N2 | c.273A>T p.I91= | Silent (SNP) | VAF 13/259 reads (5%) | catalogued as COSV60050278; called by muse, mutect2
- PNPLA6 | c.3573A>G p.V1191= (on ENST00000414982 / NM_001166111.2; = p.V1143= on NM_006702.5) | Silent (SNP) | VAF 45/113 reads (40%) | catalogued as COSV55374563; called by muse, mutect2, varscan2
- PRDM16 | c.2748G>A p.A916= | Silent (SNP) | VAF 149/355 reads (42%) | catalogued as rs370768364; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRKDC | c.6165C>T p.S2055= | Silent (SNP) | VAF 99/127 reads (78%) | catalogued as COSV58045407, COSV58057057; called by muse, mutect2, varscan2
- RIMS4 | c.291G>A p.L97= | Silent (SNP) | VAF 34/81 reads (42%) | catalogued as rs781020429, COSV65719288; called by muse, mutect2, varscan2
- SETBP1 | c.3594G>A p.P1198= | Silent (SNP) | VAF 44/130 reads (34%) | catalogued as rs200032059; called by muse, mutect2, varscan2
- SIPA1 | c.1404G>A p.T468= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as rs200729265, COSV67745493; called by muse, mutect2, varscan2
- SKIV2L | c.2181A>G p.A727= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV61712871; called by muse, mutect2, varscan2
- SLC17A9 | c.600C>T p.Y200= | Silent (SNP) | VAF 72/337 reads (21%) | catalogued as rs376311249; called by muse, mutect2, varscan2
- SLC6A4 | c.1257G>A p.A419= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs200633071, COSV55567051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13D | c.10599C>T p.G3533= | Silent (SNP) | VAF 44/234 reads (19%) | catalogued as rs1308357516, COSV50624656, COSV50665391; called by muse, mutect2, varscan2
